Somatic mutation profile of tumor specimen 0DLJX8 from CCDI case PBBZJH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 3.5 years (1,286 days).
Specimen 0DLJX8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f840c85-8ab0-4cfe-88bf-112c3346078a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLJWP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c32fa437-efe7-4a0f-a694-9dedbf606df4

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, 3'UTR 3, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.2659G>A p.V887I | Missense Mutation (SNP) | VAF 166/399 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs370157524; called by muse, mutect2, varscan2
- ALDH3A1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 211/469 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs201594817; called by muse, mutect2, varscan2
- CBLB | c.1898G>C p.G633A | Missense Mutation (SNP) | VAF 256/536 reads (48%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV51428344; called by muse, mutect2, varscan2
- DICER1 | c.5425G>A p.G1809R | Missense Mutation (SNP) | VAF 202/485 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58615244, COSV58615703, COSV58615881; called by muse, mutect2, varscan2
- KAT2B | c.2129G>C p.G710A | Missense Mutation (SNP) | VAF 184/432 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs938904555; called by muse, mutect2, varscan2
- MRM3 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 265/304 reads (87%) | SIFT tolerated (0.98); PolyPhen benign (0.009); catalogued as rs1266617049; called by muse, mutect2, varscan2
- POLR1A | c.449C>G p.P150R | Missense Mutation (SNP) | VAF 227/485 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV55692641; called by muse, mutect2, varscan2
- ZNF543 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 37/687 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.312); catalogued as rs1007275172, COSV58628590; called by muse, mutect2
- ARAP3 | c.4385C>T p.P1462L | Missense Mutation (SNP) | VAF 206/454 reads (45%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, varscan2
- CTNNB1 | c.167A>G p.D56G | Missense Mutation (SNP) | VAF 126/401 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, varscan2
- DPP6 | c.1847T>A p.F616Y (on ENST00000377770 / NM_001364500.2; = p.F554Y on NM_001936.5) | Missense Mutation (SNP) | VAF 203/437 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DUSP26 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- IMPG1 | c.1424T>G p.L475R | Missense Mutation (SNP) | VAF 73/432 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- MYMK | c.479_497del p.F160Cfs*? | Frame Shift Del (DEL) | VAF 148/448 reads (33%) | called by mutect2, varscan2
- NEK9 | c.790G>C p.V264L | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- PJA2 | c.112A>G p.R38G | Missense Mutation (SNP) | VAF 158/378 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RORB | c.253G>C p.G85R (on ENST00000396204 / NM_001365023.1; = p.G74R on NM_006914.4) | Missense Mutation (SNP) | VAF 229/523 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC10A2 | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 213/568 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SLC35F2 | c.978G>C p.M326I | Missense Mutation (SNP) | VAF 120/284 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CENPJ | c.1122A>C p.P374= | Silent (SNP) | VAF 79/537 reads (15%) | called by muse, mutect2, varscan2
- DCTPP1 | c.330C>T p.C110= | Silent (SNP) | VAF 137/281 reads (49%) | catalogued as COSV60000539; called by muse, mutect2, varscan2
- EXD3 | c.882G>A p.G294= | Silent (SNP) | VAF 191/495 reads (39%) | called by muse, mutect2, varscan2
- IL16 | c.1908G>T p.A636= | Silent (SNP) | VAF 151/319 reads (47%) | called by muse, mutect2, varscan2
- RAC3 | c.180T>C p.G60= | Silent (SNP) | VAF 237/541 reads (44%) | called by muse, mutect2, varscan2
- SH3BP5L | c.1167C>T p.R389= | Silent (SNP) | VAF 40/330 reads (12%) | called by muse, mutect2, varscan2
- GPSM2 | c.*35G>A | 3'UTR (SNP) | VAF 76/152 reads (50%) | catalogued as rs371265789; called by muse, mutect2, varscan2
- MAGEB5 | c.*60dup | 3'UTR (INS) | VAF 54/106 reads (51%) | catalogued as rs988188991; called by mutect2, varscan2
- MCCC1 | c.*39C>G | 3'UTR (SNP) | VAF 136/443 reads (31%) | called by muse, mutect2, varscan2
- RMDN1 | c.730-24T>C | Intron (SNP) | VAF 96/287 reads (33%) | called by muse, mutect2, varscan2
